Somatic mutation profile of tumor specimen TCGA-4A-A93Y-01A (aliquot TCGA-4A-A93Y-01A-11D-A36X-10) from TCGA case TCGA-4A-A93Y, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 63.6 years (23,226 days).
Specimen TCGA-4A-A93Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4ac69b0-421f-44c3-8c60-4b7f361f970a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4A-A93Y-10A (Blood Derived Normal), aliquot TCGA-4A-A93Y-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01293ae-a80c-4743-b78c-381aa13b3e06

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, Splice Site 2, 5'Flank 2, Nonsense Mutation 2, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC090517.4 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as COSV99974166; called by muse, mutect2
- ADGRG6 | c.1333A>T p.N445Y | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV99746126; called by muse, mutect2
- ARHGEF19 | c.1298+1G>A p.X433_splice | Splice Site (SNP) | VAF 7/107 reads (7%) | catalogued as COSV99580140; called by muse, mutect2
- AZGP1 | c.9A>C p.R3S | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99447731; called by muse, mutect2
- CNTLN | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.474); catalogued as COSV99263134; called by muse, mutect2
- CREBBP | c.4526A>G p.K1509R | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV99268871; called by muse, mutect2
- DHX38 | c.974A>T p.D325V | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV99194205; called by muse, mutect2
- LRP1 | c.8518G>T p.D2840Y | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99674829, COSV99675024; called by muse, mutect2
- MPC2 | c.130T>C p.W44R | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99607496; called by muse, mutect2
- MXRA5 | c.6477G>T p.R2159S | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.372); catalogued as COSV99476052; called by muse, mutect2
- MXRA5 | c.6476G>T p.R2159M | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.925); catalogued as COSV99476053; called by muse, mutect2
- OR6Q1 | c.41T>A p.F14Y | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109501; called by muse, mutect2
- RLN1 | c.54A>C p.Q18H | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV99802639; called by muse, mutect2
- RNF38 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/118 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs891070230, COSV99424820; called by muse, mutect2
- SPAG9 | c.277A>T p.K93* | Nonsense Mutation (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100004648; called by muse, mutect2, varscan2
- SRRM2 | c.4532C>T p.T1511I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.421); catalogued as COSV100070367; called by mutect2, varscan2
- SUZ12 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 14/266 reads (5%) | catalogued as COSV100496750; called by muse, mutect2
- SYCP2 | c.3556-2A>C p.X1186_splice | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100698045; called by muse, mutect2, varscan2
- ZNF142 | c.3106T>A p.F1036I (on ENST00000411696 / NM_001379660.1; = p.F836I on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101376907; called by muse, mutect2
- FIGNL2 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.1); called by muse, mutect2
- ABCC2 | c.285A>G p.T95= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV64971430; called by muse, mutect2
- CACNG3 | c.282C>T p.A94= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as rs1409857130, COSV50066019; called by muse, mutect2
- CXXC4 | c.603A>G p.L201= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV101182258; called by muse, mutect2
- OBSCN | c.9342C>A p.T3114= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99474370; called by muse, mutect2
- SPAG9 | c.276G>A p.E92= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100004653; called by muse, mutect2
- IMPDH1 | chr7:128409858 G>C | 5'Flank (SNP) | VAF 52/847 reads (6%) | catalogued as COSV100118615; called by muse, mutect2
- IMPDH1 | chr7:128409859 C>T | 5'Flank (SNP) | VAF 52/846 reads (6%) | catalogued as COSV100118616; called by muse, mutect2
- TEX12 | c.-2A>T | 5'UTR (SNP) | VAF 7/107 reads (7%) | catalogued as COSV99737527; called by muse, mutect2
